Surgical pathology report (de-identified scan), TCGA case TCGA-29-1775, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1775-01A (Primary Tumor).

[page 1 of 3]
TCGA-29-1775

Surg Path

CLINICAL HISTORY:

Malignant neoplasm of the ovary with

GROSS EXAMINATION:

A. "Small nodule", received from the OR and placed in formalin is a 1.8 x 1.1 x 0.9 cm white, rubbery mass which weighs 1.25 gram. Serial sectioning reveals a white, homogenous center with no visible necrosis or hemorrhage. The entire nodule is submitted in blocks A1-2.

B. "Bladder peritoneum", received fresh from the OR is a 4.5 x 2 x 1.2 cm aggregate of red-tan fibrofatty tissue. Representative sections of the most firm portions of this are submitted in blocks B1-2. The remaining fatty tissue is placed back in the container labeled bladder peritoneum.

C. "Left tube and ovary", received from the OR is a 6 x 5 x 4.8 cm lobulated mass attached to the fallopian tube. The mass has one large cyst (4 x 3.2 x 2 cm) filled with a viscous hemorrhagic fluid occupying roughly half of the cystic area. The remaining portion of the mass is firm and solid with a mottled appearance ranging from yellow to tan. Definite residual ovarian tissue is not identified. The attached fallopian tube (4.5 x 0.4 cm in diameter) is intact and has fimbria. Serial sectioning reveals that the distal fallopian tube (closest to the ovary) grossly appears to be encircled by the white lesion.

BLOCK SUMMARY:

C1-2- tumor plus capsule

C3- proximal mid and distal (distal is grossly involved) plus fimbria

D. "Right tube and ovary", received fresh from the OR and placed in formalin. The specimen is 6 x 5.5 x 4.8 cm, lobulated, red-tan mass which is attached to the fallopian tube (4.5 cm in length x 0.8 cm in diameter). Two cysts, the largest of which measures 3.5 x 3.2 x 2.8 cm and the smaller measures 2.5 x 1.5 x 1.4 cm. The cyst is filled with hemorrhagic viscous fluid occupying approximately 25% of the cyst. The remaining portion of the mass is firm, solid with a mottled appearance ranging from yellow to tan. The outer surface is irregular with multiple shaggy adhesions. Definite residual ovarian tissue is not identified. Serial sectioning of the fallopian tube reveals grossly tumor surrounding the distal fallopian tube or proximal fallopian tube and fimbria do not seem to be grossly involved.

BLOCK SUMMARY:

D1- tumor plus cystic portion

D2- tumor with what grossly appears to be extracapsular invasion

D3- tumor closest to the fallopian tube

D4- tumor outside of the ovary on the top surface

D5- fallopian tubes (with distal involvement) and fimbria

E. "Uterus, cervix, and bladder peritoneum", received from the OR is a 188 gram hysterectomy specimen measuring 9 x 7 x 5 cm. The cervix is 4 cm in diameter with a patent os of 1.2 cm. The bladder flap peritoneum is also attached and measures 4.5 x 6 x 0.6 cm. The ectocervix (3 x 2.8) is covered by a smooth glistening white mucosa. The external os is circular. The endocervical canal (2.8 cm) has a tan herringbone mucosa. The endometrial cavity (5 x 3.4 from cornu to cornu) has a tan-pink hemorrhagic endometrial lining. The remaining mucosa is unremarkable. The serosal surface of the uterus appears to be diffusely involved, with multiple tan-white plaque-like ulcerated lesions adherent to its surface. The bladder flap (12.5 x 6 x 0.6 cm) is attached and also appears to be diffusely involved, having the majority

[page 2 of 3]
TCGA-29-1775

of its thickness covered in tan-white, ulcerated lesion. Serial sectioning of the endometrium reveals a pink-tan cut surface with the endometrium measuring 0.1 cm and the myometrium 2 cm, otherwise the myometrium and endometrium are normal on their cut surfaces.

BLOCK SUMMARY:

- E1- posterior cervix
- E2- anterior cervix
- E3- posterior endomyometrium
- E4-5- anterior endomyometrium, bisected
- E6- mostly involved bladder flap
- E7-8- tumor adherent to the uterine serosal surface

F. "Omentum", received from the OR is a 9 x 8 x 3.5 cm aggregate of firm, yellow-tan and red hemorrhagic tissue. This tissue is unoriented and has many nodules (greater than 100). Serial sectioning reveals a glistening, multiloculated, firm, yellow surface with intermittent hemorrhage. Representative sections are submitted in blocks F1-3.

G. "Rectal donut", received fresh from the OR and subsequently placed in formalin are two circular fragments of tissue measuring 2 x 1.8 cm in aggregate. These two fragments of tissue are unoriented, tan-brown with a rubbery consistency. They are completely submitted in blocks G1-3.

H. "Portion of tumor", received from the OR and subsequently placed in formalin. The specimen is a 4 x 0.6 cm, red-tan fragment of fibrous tissue. The specimen is completely submitted in blocks H1-2.

I. "Bowel", received from the OR and subsequently placed in formalin is a 2 cm long x 5 cm wide section of small bowel with adherent tissue. The serosal surface has many (more than 80) nodules and indurated, red, rubbery excrescences, the largest which measures 3 x 2.1 x 1.5 cm. The outer portion of the bowel is red and indurated. Opening the bowel reveals corrugated soft bowel-lined mucosa which is unremarkable.

BLOCK SUMMARY:

- I1-2- margin taken tangentially
- I3- opposite margin, tangentially
- I4- adherent tumor
- I5- tumor
- I6- tumor with underlying mucosa
- I7- mucosa and overlying tumor

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY & OOPHORECTOMY

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

- D. "LEFT AND RIGHT OVARIES":
- TYPE: SEROUS ADENOCARCINOMA
- FIGO GRADE: 2.

[page 3 of 3]
TCGA-29-1775

TUMOR SIZE: 6 X 5 X 4.8 AND 6 X 5 X 4.8, RESPECTIVELY CM.
WEIGHT: NA
Serosa: INVOLVED.
ADDITIONAL FINDINGS: NONE.

WITH METASTATIC/IMPLANTED TUMOR, INVOLVING THE FOLLOWING SPECIMENS

- A. SMALL NODULE
- B. BLADDER PERITONEUM
- D. RIGHT FALLOPIAN TUBE
- E. UTERUS, 188 GRAMS
- Serosa: INVOLVED WITH TUMOR
- ENDOMETRIUM: ATROPHY.
- POLYP.
- MYOMETRIUM: NO PATHOLOGIC DIAGNOSIS.
- CERVIX: NO PATHOLOGIC DIAGNOSIS.
- BLADDER FLAP: INVOLVED.
- F. OMENTUM, EXTENSIVE.
- H. PORTION OF TUMOR.
- I. BOWEL: EXTENSIVE SEROSAL SPREAD.

SPECIMENS FREE OF TUMOR

- C. LEFT FALLOPIAN TUBE
- G. RECTAL DONUT

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file f3ab3937-7a42-4ed7-8993-1655c9b75bb4 (TCGA-29-1775.8F5DD3E0-B6C8-443E-88D9-C9D02A531F60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).